Somatic mutation profile of tumor specimen TCGA-AA-3976-01A (aliquot TCGA-AA-3976-01A-01W-0995-10) from TCGA case TCGA-AA-3976, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 70.1 years (25,599 days).
Specimen TCGA-AA-3976-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34d95239-13ef-403f-a7e7-9ecfee3d5535.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3976-10A (Blood Derived Normal), aliquot TCGA-AA-3976-10A-01W-0999-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2f46c31-0633-421f-84f6-2dcbde87d160

The open-access MAF lists 98 somatic variants for this specimen: 71 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 25, Nonsense Mutation 5, Frame Shift Del 2, Intron 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2701C>T p.Q901* | Nonsense Mutation (SNP) | VAF 32/76 reads (42%) | catalogued as rs1114167559, CM105838, COSV57381203; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 62/101 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 130/241 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- TP53 | c.796G>T p.G266* | Nonsense Mutation (SNP) | VAF 49/60 reads (82%) | hotspot (GDC flag); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; called by muse, mutect2, varscan2
- ALK | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 157/212 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775514690, COSV101202766; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APP | c.451C>T p.H151Y | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV61002703; called by muse, mutect2
- ARSH | c.773G>A p.R258K | Missense Mutation (SNP) | VAF 83/172 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as COSV66963624; called by muse, mutect2, varscan2
- BBS10 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.022); catalogued as COSV99675672; called by muse, mutect2, varscan2
- BPIFA3 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.117); catalogued as rs779915382, COSV100967136; called by muse, mutect2, varscan2
- CD22 | c.1774G>A p.A592T | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV99323820; called by muse, mutect2, varscan2
- CDH11 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 112/607 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51765159; called by muse, mutect2, varscan2
- CHST4 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.219); catalogued as rs746879634, COSV58296441; called by muse, mutect2, varscan2
- CLSTN2 | c.1784C>T p.T595M | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368537354, COSV101515431; called by muse, mutect2, varscan2
- COQ9 | c.342C>A p.H114Q | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV99346024; called by muse, mutect2, varscan2
- CPD | c.3027A>T p.E1009D | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.835); catalogued as COSV99853320; called by muse, mutect2
- CYBB | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 122/150 reads (81%) | SIFT tolerated (0.11); PolyPhen benign (0.417); catalogued as rs781797749, COSV66085714; called by muse, mutect2, varscan2
- DENND3 | c.2870A>G p.N957S | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99370887; called by muse, mutect2
- DHTKD1 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs141125831; called by muse, mutect2, varscan2
- FAT4 | c.6188C>A p.T2063K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100630408; called by muse, mutect2, varscan2
- FBXL2 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs1022223193, COSV99372320; called by muse, mutect2, varscan2
- FCAR | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs143972917; called by muse, mutect2
- GCOM1 | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV99985381; called by muse, mutect2, varscan2
- GPC5 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 57/397 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.031); catalogued as rs772585092, COSV65583951; called by muse, mutect2, varscan2
- GPX1 | c.489C>G p.N163K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV69043241; called by muse, mutect2, varscan2
- HERC2 | c.8146A>G p.I2716V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as rs553201610; called by muse, mutect2, varscan2
- IL26 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 60/346 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs373868127; called by muse, mutect2, varscan2
- IMMP2L | c.306-2_306-1insT p.X102_splice | Splice Site (INS) | VAF 85/215 reads (40%) | catalogued as COSV59259852; called by mutect2, pindel, varscan2
- ITGB1 | c.17T>G p.I6S | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV56485133; called by muse, mutect2, varscan2
- LRRC7 | c.3683C>T p.P1228L (on ENST00000651989 / NM_001370785.2; = p.P1195L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as rs372250538; called by muse, mutect2, varscan2
- LRTM1 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 112/299 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs149325578, COSV55582428; called by muse, mutect2, varscan2
- MAN2A1 | c.1923A>G p.I641M | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV54857637; called by muse, mutect2, varscan2
- MED12 | c.99G>T p.E33D | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV61336158; called by muse, mutect2, varscan2
- MOS | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as rs1048011369, COSV61337001; called by muse, mutect2
- NEXN | c.1171C>T p.R391* | Nonsense Mutation (SNP) | VAF 10/18 reads (56%) | catalogued as rs200106758; called by muse, mutect2, varscan2
- NLRP12 | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs147810259; called by muse, mutect2, varscan2
- OPRK1 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200672427, COSV55568081; called by muse, mutect2, varscan2
- OR13C9 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.362); catalogued as COSV99403571; called by muse, mutect2, varscan2
- OR52H1 | c.661G>A p.A221T (on ENST00000322653; = p.A227T on NM_001005289.1) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs371667578; called by muse, mutect2, varscan2
- PCDH15 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 101/351 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.547); catalogued as rs1402798500, COSV57307241; called by muse, mutect2, varscan2
- PCDHGA2 | c.1868C>T p.T623M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs370683887; called by muse, mutect2, varscan2
- PCLO | c.10288A>G p.M3430V | Missense Mutation (SNP) | VAF 116/218 reads (53%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV61655749; called by muse, mutect2, varscan2
- PIWIL2 | c.62C>A p.A21D | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.665); catalogued as COSV100769566, COSV63253430; called by muse, mutect2
- PLPPR4 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64565001; called by muse, mutect2, varscan2
- PSG7 | c.531C>A p.S177R | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as rs372381292; called by muse, mutect2, varscan2
- RAG1 | c.2009C>T p.T670M | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.999); catalogued as rs139863630; called by muse, mutect2, varscan2
- ROBO1 | c.2029G>T p.V677F | Missense Mutation (SNP) | VAF 106/327 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV71394859, COSV71397226; called by muse, mutect2, varscan2
- RPH3A | c.988G>C p.E330Q (on ENST00000389385 / NM_001143854.2; = p.E326Q on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV101231903; called by muse, mutect2, varscan2
- SLC32A1 | c.743C>T p.T248M | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV54146196; called by muse, mutect2, varscan2
- SLITRK1 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV65677278; called by muse, mutect2, varscan2
- SPOUT1 | c.96A>T p.K32N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV100223880; called by muse, mutect2, varscan2
- STMN4 | c.274G>A p.E92K (on ENST00000265770 / NM_001283054.2; = p.E119K on NM_030795.4) | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV56109832; called by muse, mutect2, varscan2
- SV2A | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 14/287 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as rs782745503, COSV64966342; called by muse, mutect2
- TECPR2 | c.2399C>A p.A800E | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100850236; called by muse, mutect2
- TECTA | c.2047G>A p.V683I | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs928587604, COSV99881722; called by muse, mutect2, varscan2
- TEP1 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 160/413 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs147598692; called by muse, mutect2, varscan2
- TF | c.1846G>A p.V616I | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.226); catalogued as rs146055081, COSV53925264; called by muse, mutect2, varscan2
- TMEM144 | c.146G>A p.W49* | Nonsense Mutation (SNP) | VAF 247/767 reads (32%) | catalogued as COSV56702281; called by muse, mutect2, varscan2
- TRANK1 | c.2596C>T p.R866* | Nonsense Mutation (SNP) | VAF 21/82 reads (26%) | catalogued as rs535417879, COSV100084941; called by muse, mutect2, varscan2
- TSHZ2 | c.2934G>C p.Q978H | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs748087634, COSV61590306, COSV61591024; called by muse, mutect2, varscan2
- TTC14 | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.022); catalogued as rs150698778, COSV56009722; called by muse, mutect2, varscan2
- UNC13B | c.359A>C p.K120T | Missense Mutation (SNP) | VAF 111/346 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.15); catalogued as rs778739015, COSV101037455; called by muse, mutect2, varscan2
- ZFHX4 | c.9580A>G p.T3194A | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV99268363; called by muse, mutect2, varscan2
- ZHX2 | c.2368G>A p.V790I | Missense Mutation (SNP) | VAF 55/324 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs148101741; called by muse, mutect2, varscan2
- ZNF10 | c.264G>T p.E88D | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV99940195; called by muse, mutect2
- ZNF208 | c.3174A>C p.K1058N | Missense Mutation (SNP) | VAF 74/142 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs752001805, COSV68110676; called by muse, mutect2, varscan2
- ZNF521 | c.3457C>A p.L1153I | Missense Mutation (SNP) | VAF 119/398 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100833521; called by muse, mutect2, varscan2
- ZNF875 | c.822G>A p.M274I | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100183589; called by muse, mutect2, varscan2
- APBB1 | c.1509G>A p.M503I | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- APC | c.4240del p.V1414* | Frame Shift Del (DEL) | VAF 40/123 reads (33%) | called by mutect2, pindel, varscan2
- MYBL1 | c.318del p.P107Qfs*6 | Frame Shift Del (DEL) | VAF 171/658 reads (26%) | called by mutect2, pindel, varscan2
- WDR38 | c.782A>G p.D261G | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- AHI1 | c.1857C>T p.H619= | Silent (SNP) | VAF 84/355 reads (24%) | catalogued as COSV55632928; called by muse, mutect2, varscan2
- AMDHD1 | c.525C>T p.R175= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs1211928181, COSV57137771; called by muse, mutect2, varscan2
- ANAPC7 | c.348G>A p.V116= | Silent (SNP) | VAF 24/440 reads (5%) | catalogued as COSV101484814, COSV71443979; called by muse, mutect2
- ANO3 | c.609C>T p.P203= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as rs778253031, COSV99883362; called by muse, mutect2, varscan2
- CDH8 | c.1866C>T p.G622= | Silent (SNP) | VAF 54/140 reads (39%) | catalogued as COSV54857645; called by muse, mutect2, varscan2
- CNN1 | c.114C>T p.I38= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as rs1221016776, COSV52955878; called by muse, mutect2, varscan2
- DMXL1 | c.2178C>T p.A726= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV100225110; called by muse, mutect2, varscan2
- GZMH | c.396C>T p.S132= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs1255793335; called by muse, mutect2
- HDGFL1 | c.45G>A p.V15= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV57752733; called by muse, mutect2, varscan2
- INSR | c.2967A>G p.G989= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs776148714, COSV57169874; called by muse, mutect2, varscan2
- LRRC3B | c.15C>T p.D5= | Silent (SNP) | VAF 348/829 reads (42%) | catalogued as COSV67522121; called by muse, mutect2, varscan2
- MINDY4 | c.1122C>T p.A374= | Silent (SNP) | VAF 93/423 reads (22%) | catalogued as rs545068622, COSV54677096; called by muse, mutect2, varscan2
- MLLT1 | c.387G>A p.T129= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs760101990, COSV53132235; called by muse, mutect2, varscan2
- NTNG2 | c.942C>T p.P314= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs145479097, COSV62368178; called by muse, mutect2, varscan2
- OLFM2 | c.849C>T p.Y283= | Silent (SNP) | VAF 38/70 reads (54%) | catalogued as COSV53432697; called by muse, mutect2, varscan2
- PCDHB15 | c.1530C>T p.N510= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs1554292103, COSV50895175; called by muse, mutect2, varscan2
- PDGFB | c.672G>T p.R224= | Silent (SNP) | VAF 51/145 reads (35%) | catalogued as COSV58649080, COSV58649271; called by muse, mutect2, varscan2
- RILPL1 | c.834C>T p.D278= | Silent (SNP) | VAF 45/116 reads (39%) | catalogued as rs370215117; called by muse, mutect2, varscan2
- SNTG2 | c.708G>A p.T236= | Silent (SNP) | VAF 55/68 reads (81%) | catalogued as rs202059053, COSV57967552; called by muse, mutect2, varscan2
- SORT1 | c.1236C>T p.G412= | Silent (SNP) | VAF 77/256 reads (30%) | catalogued as rs781587744, COSV56668659; called by muse, mutect2, varscan2
- SRSF12 | c.780T>C p.S260= | Silent (SNP) | VAF 66/174 reads (38%) | catalogued as rs913583391, COSV71683754; called by muse, mutect2, varscan2
- SVEP1 | c.4383C>T p.D1461= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs368920627; called by muse, mutect2, varscan2
- TBC1D9 | c.1050G>A p.P350= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs376544697; called by muse, varscan2
- THSD1 | c.1698G>A p.A566= | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as rs753100705, COSV51630554; called by muse, mutect2, varscan2
- ZBTB11 | c.900C>A p.V300= | Silent (SNP) | VAF 117/264 reads (44%) | catalogued as COSV57246332; called by muse, mutect2, varscan2
- CACNA1C | c.2853+182T>C | Intron (SNP) | VAF 49/158 reads (31%) | catalogued as COSV100222748; called by muse, mutect2, varscan2
- EPB41L4B | c.1409+1832C>T | Intron (SNP) | VAF 74/406 reads (18%) | catalogued as rs368537840; called by muse, mutect2, varscan2
